Somatic mutation profile of tumor specimen C3N-03415-01 (aliquot CPT0247910006) from CPTAC case C3N-03415, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 85.8 years (31,332 days).
Specimen C3N-03415-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c1a580b-c9ab-46bc-b06e-8d065dfaab5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03415-31 (Blood Derived Normal), aliquot CPT0247930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/220825e7-c7df-4329-b980-9c9e3e51a575

The open-access MAF lists 8,136 somatic variants for this specimen: 5,360 protein-altering or splice-affecting, 1,808 silent, 968 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,496, Silent 1,808, Intron 512, Frame Shift Del 333, 3'UTR 171, Splice Site 148, Frame Shift Ins 128, Nonsense Mutation 124, RNA 106, Splice Region 104, 5'UTR 87, 5'Flank 48.

Variants (750 of 8,136; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS2 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 49/473 reads (10%) | catalogued as rs587777591, CM146227; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGL | c.3911dup p.N1304Kfs*7 | Frame Shift Ins (INS) | VAF 55/176 reads (31%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATM | c.8432dup p.S2812Vfs*3 | Frame Shift Ins (INS) | VAF 38/124 reads (31%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 176/442 reads (40%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- CACNA1C | c.2500A>G p.K834E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.952); catalogued as rs1555836187, CM135622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSF1R | c.1879_1881del p.K627del | In Frame Del (DEL) | VAF 41/117 reads (35%) | catalogued as rs1554101963; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- F8 | c.5123G>A p.R1708H | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111033614, CM062654, CM910137, COSV64275688; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.506del p.G169Afs*23 | Frame Shift Del (DEL) | VAF 84/250 reads (34%) | catalogued as rs1452295073; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FOXP1 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 85/205 reads (41%) | catalogued as rs112795301, CM107720, COSV59537299; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GUCY1A1 | c.488dup p.L163Ffs*24 | Frame Shift Ins (INS) | VAF 57/213 reads (27%) | catalogued as rs587777928; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LDLR | c.1748A>G p.H583R | Missense Mutation (SNP) | VAF 232/577 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879255007, CM127021; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 23/166 reads (14%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 140/377 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- NOTCH1 | c.5950C>T p.R1984* | Nonsense Mutation (SNP) | VAF 12/308 reads (4%) | catalogued as rs1554826746, COSV53039810; ClinVar: pathogenic; called by muse, mutect2
- PKD2 | c.2159dup p.N720Kfs*5 | Frame Shift Ins (INS) | VAF 114/315 reads (36%) | catalogued as rs757757289; ClinVar: pathogenic; called by mutect2, varscan2
- POLG | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 130/348 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs753416225, CM158664, COSV51519891; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 63/188 reads (34%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RHOA | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 19/200 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV69041520, COSV69042084; called by muse, mutect2
- RNASEH2C | c.450G>A p.W150* | Nonsense Mutation (SNP) | VAF 50/549 reads (9%) | catalogued as rs1064793942; ClinVar: pathogenic; called by muse, mutect2
- SZT2 | c.5872C>T p.R1958* (on ENST00000634258 / NM_001365999.1; = p.R1901* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 138/318 reads (43%) | catalogued as rs145577757; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TGFB2 | c.821dup p.N274Kfs*19 | Frame Shift Ins (INS) | VAF 70/198 reads (35%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TGM1 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 165/445 reads (37%) | catalogued as rs760429286, CM951201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as rs763404617, COSV55541081; called by muse, mutect2, varscan2
- ABCA1 | c.4176-1G>A p.X1392_splice | Splice Site (SNP) | VAF 186/506 reads (37%) | catalogued as COSV101037891; called by muse, mutect2, varscan2
- ABCB9 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs745962274; called by muse, mutect2, varscan2
- ABCC1 | c.3468C>A p.N1156K | Missense Mutation (SNP) | VAF 123/380 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs766636573, COSV100580416; called by muse, mutect2, varscan2
- ABCC1 | c.4396G>A p.D1466N | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs368326285; called by muse, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCF1 | c.503A>T p.E168V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as COSV58228107; called by muse, varscan2
- ABCF3 | c.1298A>G p.Y433C | Missense Mutation (SNP) | VAF 135/357 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as COSV53052160; called by muse, mutect2, varscan2
- ABCG5 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs1181566629; called by muse, varscan2
- ACACB | c.769del p.D257Ifs*17 | Frame Shift Del (DEL) | VAF 60/225 reads (27%) | catalogued as rs768607691; called by mutect2, pindel, varscan2
- ACACB | c.5056C>T p.P1686S | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV58142013; called by muse, mutect2
- ACAP3 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 192/492 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as rs1367187385, COSV57640029; called by muse, mutect2, varscan2
- ACCSL | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV66580741; called by muse, mutect2, varscan2
- ACER1 | c.151T>C p.Y51H | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177032711; called by muse, mutect2, varscan2
- ACO2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 239/686 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as rs1225988907; called by muse, mutect2, varscan2
- ACOT2 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 58/365 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.894); catalogued as rs765886993; called by muse, mutect2, varscan2
- ACP3 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs142280067; called by muse, mutect2, varscan2
- ACSL3 | c.1615T>C p.Y539H | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62480560; called by muse, mutect2
- ACSL6 | c.1639G>A p.A547T (on ENST00000379240; = p.A572T on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs773386832; called by muse, mutect2
- ACTB | c.364-3C>T | Splice Region (SNP) | VAF 150/364 reads (41%) | catalogued as rs1562719316; called by muse, mutect2, varscan2
- ACTL9 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV61004774; called by muse, mutect2, varscan2
- ADAM12 | c.424A>G p.R142G | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1317524940, COSV100901828; called by muse, mutect2, varscan2
- ADAM15 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 103/446 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs763997945; called by muse, mutect2, varscan2
- ADAM18 | c.631dup p.I211Nfs*30 | Frame Shift Ins (INS) | VAF 25/78 reads (32%) | catalogued as rs771066100; called by mutect2, pindel, varscan2
- ADAMTS20 | c.2355del p.E786Kfs*86 | Frame Shift Del (DEL) | VAF 38/140 reads (27%) | catalogued as rs1177283960; called by mutect2, varscan2
- ADAMTS3 | c.3182A>G p.Y1061C | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); catalogued as rs1252502850; called by muse, mutect2, varscan2
- ADAT3 | c.820dup p.Q274Pfs*10 | Frame Shift Ins (INS) | VAF 73/244 reads (30%) | catalogued as rs775575809; called by mutect2, pindel, varscan2
- ADCK2 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 145/393 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1400624340; called by muse, mutect2, varscan2
- ADCK5 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 199/503 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781835742, COSV104395016; called by muse, mutect2, varscan2
- ADCY3 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as rs1160906463, COSV53170465; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1165G>A p.G389S | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100416680; called by muse, mutect2, varscan2
- ADGRA3 | c.3509G>T p.R1170L | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV51560464; called by muse, mutect2, varscan2
- ADGRD2 | c.2235G>A p.E745= | Splice Region (SNP) | VAF 110/280 reads (39%) | catalogued as rs1333360195; called by muse, mutect2, varscan2
- ADGRF3 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 23/283 reads (8%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.055); catalogued as COSV100275050; called by muse, mutect2
- ADIPOQ | c.290T>A p.I97N | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs370574236; called by muse, mutect2, varscan2
- AEBP1 | c.2383del p.E795Rfs*32 | Frame Shift Del (DEL) | VAF 39/387 reads (10%) | catalogued as COSV56260153; called by mutect2, pindel, varscan2
- AFF3 | c.1030A>G p.N344D | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1347214176; called by muse, mutect2, varscan2
- AGAP3 | c.1054A>G p.K352E (on ENST00000622464; = p.K388E on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/346 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs766246578; called by muse, mutect2, varscan2
- AGAP6 | c.73T>C p.C25R | Missense Mutation (SNP) | VAF 263/824 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.384); catalogued as COSV65018191; called by muse, mutect2, varscan2
- AGL | c.4124A>G p.Y1375C | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs886042149, COSV54047348; ClinVar: uncertain significance; called by muse, mutect2
- AGTR1 | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1241893519; called by muse, mutect2, varscan2
- AHCTF1 | c.3283T>A p.S1095T (on ENST00000366508; = p.S1069T on NM_015446.5) | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV58246111; called by muse, mutect2, varscan2
- AJM1 | c.2680G>T p.A894S | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV99915769; called by muse, mutect2, varscan2
- AK5 | c.1096A>G p.M366V (on ENST00000354567 / NM_174858.3; = p.M340V on NM_012093.4) | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs769202282, COSV60972655; called by muse, mutect2, varscan2
- AKAP13 | c.1594A>G p.S532G | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs868652104, COSV100774090; called by muse, mutect2, varscan2
- AKAP6 | c.3101T>C p.L1034P | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV55208996; called by muse, mutect2, varscan2
- AKAP6 | c.*44T>C | Splice Region (SNP) | VAF 23/151 reads (15%) | catalogued as COSV55206725; called by muse, mutect2
- AKAP8L | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs370436991; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 96/286 reads (34%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKR1C1 | c.586T>C p.Y196H | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373617440; called by muse, mutect2
- AKR7A2 | c.443C>A p.P148Q | Missense Mutation (SNP) | VAF 64/507 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs201888607; called by muse, mutect2, varscan2
- ALDH3A1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV56735029; called by muse, mutect2, varscan2
- ALDH9A1 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 49/172 reads (28%) | catalogued as rs1050923147; called by muse, mutect2, varscan2
- ALG3 | c.195A>G p.A65= | Splice Region (SNP) | VAF 26/68 reads (38%) | catalogued as rs1360281464; called by muse, mutect2, varscan2
- ALMS1 | c.9484A>G p.I3162V | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.771); catalogued as rs751131826; called by muse, mutect2, varscan2
- ALX4 | c.781T>C p.W261R | Missense Mutation (SNP) | VAF 43/394 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61326653; called by muse, mutect2, varscan2
- ANHX | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs566321789; called by muse, varscan2
- ANK3 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55061898; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.7750dup p.L2584Pfs*24 | Frame Shift Ins (INS) | VAF 31/147 reads (21%) | catalogued as rs768378604; called by mutect2, pindel, varscan2
- ANKRD11 | c.5552A>G p.Y1851C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); catalogued as rs376366933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD24 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 118/285 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as rs371791696, COSV99518003; called by muse, mutect2, varscan2
- ANKRD26 | c.4052A>G p.K1351R | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as COSV65776117; called by muse, mutect2, varscan2
- ANKS3 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as rs761239350; called by muse, mutect2, varscan2
- ANO1 | c.1606G>T p.G536C | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773592156; called by muse, mutect2, varscan2
- ANP32D | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as rs890426022; called by muse, mutect2, varscan2
- AOC2 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1029119701; called by muse, varscan2
- AP1B1 | c.1699A>G p.I567V | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as rs1360184297; called by muse, mutect2, varscan2
- AP3D1 | c.2363G>A p.S788N | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100642415; called by muse, mutect2
- AP5Z1 | c.1772A>G p.Y591C | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs747261565; called by muse, mutect2, varscan2
- APAF1 | c.1352G>A p.S451N (on ENST00000551964 / NM_181861.2; = p.S440N on NM_001160.3) | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV59667806; called by muse, varscan2
- APBA1 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1564062638, COSV55228003; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | catalogued as rs546686089; called by mutect2, varscan2
- APOH | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs756210824; called by muse, mutect2, varscan2
- APOOL | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100920801; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 80/281 reads (28%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARFGEF2 | c.3533G>T p.R1178L | Missense Mutation (SNP) | VAF 157/402 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64211768; called by muse, mutect2, varscan2
- ARHGAP45 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 72/207 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1304006735, COSV57430711; called by muse, varscan2
- ARHGDIA | c.535T>A p.S179T | Missense Mutation (SNP) | VAF 207/559 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53907011; called by muse, mutect2, varscan2
- ARHGEF5 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 273/1545 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as rs759538835; called by muse, mutect2, varscan2
- ARID1A | c.4513A>G p.T1505A | Missense Mutation (SNP) | VAF 52/414 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs753094331, COSV61378247; called by muse, varscan2
- ARID1B | c.249G>C p.Q83H | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51658513; called by muse, varscan2
- ARID1B | c.6530C>T p.P2177L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1450272524; called by muse, mutect2, varscan2
- ARID4A | c.521T>C p.L174S | Missense Mutation (SNP) | VAF 85/226 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1227632306; called by muse, mutect2, varscan2
- ARL16 | c.278G>C p.S93T | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV61270072; called by muse, mutect2, varscan2
- ARL6IP1 | c.223A>G p.M75V | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV100435781; called by muse, mutect2, varscan2
- ARMC4 | c.2393G>A p.G798D | Missense Mutation (SNP) | VAF 33/492 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59470878; called by muse, mutect2
- ARNT2 | c.2009G>A p.G670D | Missense Mutation (SNP) | VAF 106/358 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs865957087; called by muse, mutect2, varscan2
- ARRDC2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 168/472 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs770483953, COSV99716684; called by muse, mutect2, varscan2
- ASAP1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100728028; called by muse, mutect2, varscan2
- ASAP1 | c.989A>G p.Y330C | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV100727657; called by muse, mutect2, varscan2
- ASNS | c.1517C>A p.P506H | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV51555901; called by muse, mutect2, varscan2
- ASPM | c.8405G>A p.G2802D | Missense Mutation (SNP) | VAF 154/609 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.157); catalogued as COSV54136920; called by muse, mutect2, varscan2
- ASS1 | c.175-2A>G p.X59_splice | Splice Site (SNP) | VAF 130/366 reads (36%) | catalogued as rs1321267678; called by muse, varscan2
- ASXL1 | c.3218G>A p.R1073H | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as rs1444168328, COSV60104419, COSV60107297; called by muse, mutect2, varscan2
- ASXL3 | c.5813C>T p.A1938V | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.081); catalogued as COSV52457919; called by muse, mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 64/198 reads (32%) | catalogued as rs1558707706; called by mutect2, pindel, varscan2
- ATF7 | c.1001G>A p.R334Q (on ENST00000548446 / NM_001366555.2; = p.R323Q on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/243 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs763653671; called by muse, mutect2, varscan2
- ATP10B | c.2951C>T p.S984F | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); catalogued as COSV59155766; called by muse, mutect2, varscan2
- ATP11B | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs375942497; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP11C | c.3210G>A p.W1070* | Nonsense Mutation (SNP) | VAF 34/119 reads (29%) | catalogued as rs1295591659; called by muse, mutect2, varscan2
- ATP13A5 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV60868201; called by mutect2, varscan2
- ATP1A4 | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV63627026; called by muse, mutect2
- ATP2B2 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); catalogued as COSV59496479; called by muse, mutect2, varscan2
- ATP2B4 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 116/411 reads (28%) | catalogued as rs780709781, COSV58180142; called by muse, mutect2, varscan2
- ATP2B4 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 149/565 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184472955; called by muse, mutect2, varscan2
- ATP2C1 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CS126174; called by muse, mutect2
- ATP2C2 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs771547390; called by muse, mutect2, varscan2
- ATP4A | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs753188424; called by muse, mutect2, varscan2
- ATP5MF-PTCD1 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52855652; called by muse, mutect2, varscan2
- ATP6V0C | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53549651; called by muse, mutect2, varscan2
- ATP6V1E2 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100120746; called by muse, mutect2, varscan2
- ATP7B | c.1852A>G p.I618V | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV54438195; called by muse, mutect2, varscan2
- ATP8A1 | c.2894A>G p.Y965C | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV52529262; called by muse, mutect2, varscan2
- ATP8B3 | c.818A>G p.D273G | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs780337237; called by muse, mutect2
- ATP9A | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 55/136 reads (40%) | catalogued as rs937920116; called by muse, mutect2, varscan2
- ATRN | c.2525T>C p.M842T | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs1387267890; called by muse, mutect2
- AUH | c.613dup p.M205Nfs*5 | Frame Shift Ins (INS) | VAF 113/386 reads (29%) | catalogued as rs1564075054; called by mutect2, pindel, varscan2
- AXIN1 | c.2258T>C p.V753A | Missense Mutation (SNP) | VAF 30/713 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.108); catalogued as rs1290523788; called by muse, mutect2
- B3GNT9 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs1182040815; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 30/254 reads (12%) | catalogued as rs35951843; called by mutect2, varscan2
- B4GALT6 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV52702858; called by muse, mutect2, varscan2
- BAG5 | c.430T>C p.S144P | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as rs1189534498; called by muse, mutect2, varscan2
- BAZ1A | c.4094A>G p.N1365S | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV62411497; called by muse, mutect2
- BCAR1 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.535); catalogued as rs777661393; called by muse, mutect2, varscan2
- BCAR1 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs201347528, COSV50780018; called by muse, mutect2, varscan2
- BCR | c.3658A>G p.K1220E | Missense Mutation (SNP) | VAF 183/546 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as rs376756021; called by muse, mutect2, varscan2
- BEND3 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 150/416 reads (36%) | catalogued as COSV99068813; called by muse, mutect2, varscan2
- BHLHE41 | c.884del p.G295Afs*22 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs768631639; called by pindel, varscan2
- BIN2 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs774206846; called by muse, mutect2, varscan2
- BMP5 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376923719; called by muse, mutect2, varscan2
- BNC1 | c.198C>T p.H66= | Splice Region (SNP) | VAF 51/129 reads (40%) | catalogued as rs753116483, COSV61757150; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 21/52 reads (40%) | catalogued as rs749043197; called by mutect2, varscan2
- BRI3BP | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 178/489 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1255652639; called by muse, mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs746043904; called by mutect2, varscan2
- BRWD1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs1404978034; called by muse, mutect2, varscan2
- BSPH1 | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1399637711; called by muse, mutect2, varscan2
- BTBD11 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1303952372; called by muse, mutect2
- BTBD11 | c.2048G>A p.G683D (on ENST00000280758 / NM_001018072.2; = p.G220D on NM_001017523.2) | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs1410341054; called by muse, mutect2, varscan2
- BTBD2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 173/522 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as rs1425312152; called by muse, mutect2, varscan2
- BTBD6 | c.1057T>C p.Y353H | Missense Mutation (SNP) | VAF 24/550 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59266414; called by muse, mutect2
- BTNL3 | c.1352A>T p.D451V | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61565456; called by muse, mutect2, varscan2
- C11orf94 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as rs774192761; called by mutect2, varscan2
- C11orf95 | c.1619A>G p.E540G | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV58027625; called by muse, mutect2, varscan2
- C11orf95 | c.193del p.L65Cfs*50 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as rs1284173834; called by mutect2, pindel, varscan2
- C16orf70 | c.356-8C>G | Splice Region (SNP) | VAF 144/388 reads (37%) | catalogued as rs769158533; called by muse, mutect2, varscan2
- C17orf50 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 84/256 reads (33%) | catalogued as rs1555602353; called by muse, mutect2, varscan2
- C18orf25 | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs780281405; called by muse, mutect2, varscan2
- C19orf25 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.125); catalogued as rs1316970009; called by muse, mutect2, varscan2
- C1QB | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV59245541; called by muse, mutect2, varscan2
- C1QB | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 90/225 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV59244996; called by muse, mutect2, varscan2
- C1QTNF4 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 88/254 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs1306420309; called by muse, mutect2, varscan2
- C1S | c.479del p.P160Rfs*9 | Frame Shift Del (DEL) | VAF 148/460 reads (32%) | catalogued as rs1555161771, COSV104410645; called by mutect2, pindel, varscan2
- C1orf105 | c.198+2T>C p.X66_splice | Splice Site (SNP) | VAF 15/67 reads (22%) | catalogued as rs1344989998; called by muse, mutect2, varscan2
- C1orf122 | c.268del p.Q90Sfs*42 | Frame Shift Del (DEL) | VAF 83/214 reads (39%) | catalogued as rs747134922; called by mutect2, pindel, varscan2
- C1orf194 | c.88C>T p.P30S (on ENST00000369948 / NM_001245025.3; = p.P18S on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.188); catalogued as COSV64049721; called by muse, varscan2
- C21orf91 | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1203570051; called by muse, mutect2, varscan2
- C2CD4C | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as rs1342752455; called by muse, mutect2, varscan2
- C4orf48 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs1173177673; called by muse, mutect2
- C5AR1 | c.368G>C p.S123T | Missense Mutation (SNP) | VAF 124/310 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61893156; called by muse, mutect2, varscan2
- C7orf57 | c.620del p.N207Tfs*92 | Frame Shift Del (DEL) | VAF 42/115 reads (37%) | catalogued as rs775739111; called by mutect2, pindel, varscan2
- C8orf89 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1316911471; called by muse, mutect2, varscan2
- CABP1 | c.418del p.Q140Rfs*136 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs1157698160; called by mutect2, pindel, varscan2
- CACFD1 | c.76T>C p.W26R | Missense Mutation (SNP) | VAF 21/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1554797951; called by muse, mutect2
- CACNA1D | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 206/554 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV55461378, COSV99856742; called by muse, mutect2, varscan2
- CACNA1E | c.3572A>G p.Y1191C | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1352285149; called by muse, mutect2
- CACNA2D3 | c.2750C>T p.A917V | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs762386752; called by muse, mutect2, varscan2
- CACNB2 | c.499G>A p.G167S (on ENST00000324631 / NM_201596.3; = p.G112S on NM_000724.4) | Missense Mutation (SNP) | VAF 168/437 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs1416898728, CM144350; called by muse, mutect2, varscan2
- CADPS | c.149del p.G50Afs*48 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as rs1266879415; called by pindel, varscan2
- CAGE1 | c.1741A>G p.T581A (on ENST00000512086; = p.T445A on NM_205864.3) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs759744070; called by muse, mutect2, varscan2
- CALHM2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 255/643 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as rs563890909, COSV53296522; called by muse, mutect2, varscan2
- CALR3 | c.406A>G p.I136V | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1420658492; called by muse, mutect2, varscan2
- CAMK4 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56671296; called by muse, mutect2
- CASKIN1 | c.4148C>T p.A1383V | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748621679; called by muse, varscan2
- CASP12 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 156/408 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1248773795; called by muse, mutect2, varscan2
- CASP14 | c.26A>G p.E9G | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as rs1303853824; called by muse, mutect2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 78/190 reads (41%) | catalogued as rs765105588; called by mutect2, varscan2
- CATSPER1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 173/491 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs768910453; called by muse, mutect2, varscan2
- CATSPERD | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV101062705; called by muse, mutect2, varscan2
- CBARP | c.1954G>T p.G652C | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.268); catalogued as rs760327971; called by muse, varscan2
- CBLN4 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); catalogued as COSV99290427; called by muse, mutect2, varscan2
- CBR1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as rs747389864; called by muse, mutect2, varscan2
- CBWD5 | c.1067G>A p.R356Q (on ENST00000382405 / NM_001330668.1; = p.R308Q on NM_001024916.3) | Missense Mutation (SNP) | VAF 63/644 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.248); catalogued as rs1264760754; called by muse, mutect2, varscan2
- CC2D1B | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.664); catalogued as rs375000208; called by muse, mutect2, varscan2
- CCDC102B | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV100103875; called by muse, mutect2, varscan2
- CCDC136 | c.2416A>G p.T806A | Missense Mutation (SNP) | VAF 166/457 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs8180870; called by muse, mutect2, varscan2
- CCDC151 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 98/277 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772475736; called by muse, mutect2, varscan2
- CCDC154 | c.1432del p.Q478Sfs*3 | Frame Shift Del (DEL) | VAF 56/187 reads (30%) | catalogued as rs1259977185, COSV101209690; called by mutect2, pindel, varscan2
- CCDC17 | c.701T>A p.V234E | Missense Mutation (SNP) | VAF 131/326 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs1312730144; called by muse, mutect2, varscan2
- CCDC178 | c.1978A>G p.K660E (on ENST00000383096 / NM_001105528.3; = p.K622E on NM_198995.3) | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1343007254, COSV55767315; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2*
- CCDC180 | c.2384A>G p.H795R | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV63830294; called by muse, mutect2
- CCDC180 | c.3260G>A p.C1087Y | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1348964646; called by muse, mutect2, varscan2
- CCDC185 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs762723314; called by muse, mutect2, varscan2
- CCDC24 | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 82/457 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs761859315; called by muse, mutect2, varscan2
- CCDC24 | c.497+6G>A | Splice Region (SNP) | VAF 84/196 reads (43%) | catalogued as rs760330864; called by muse, varscan2
- CCDC73 | c.315+2T>C p.X105_splice | Splice Site (SNP) | VAF 32/88 reads (36%) | catalogued as COSV100066694; called by muse, mutect2
- CCNK | c.1000A>G p.K334E | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as rs200503921; called by muse, mutect2, varscan2
- CCNO | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 83/698 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1368356867; called by muse, varscan2
- CCNY | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 94/306 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV55189183; called by muse, varscan2
- CCT3 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs1400661078, COSV55290390; called by muse, mutect2
- CD180 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV56517448; called by muse, mutect2, varscan2
- CD27 | c.28T>C p.C10R | Missense Mutation (SNP) | VAF 115/293 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs1032225550; called by muse, mutect2, varscan2
- CD2BP2 | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 163/378 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV59770249; called by muse, mutect2
- CD40LG | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1189105308; called by muse, mutect2
- CD53 | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs757502332; called by muse, mutect2, varscan2
- CDC27 | c.886T>C p.S296P | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs76383230; called by muse, mutect2, varscan2
- CDC37 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 94/309 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as rs1009740161; called by muse, mutect2, varscan2
- CDH24 | c.1286G>A p.G429D | Missense Mutation (SNP) | VAF 192/467 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57460913; called by muse, mutect2, varscan2
- CDH7 | c.1333A>G p.N445D | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.366); catalogued as COSV59891983; called by muse, mutect2
- CDHR2 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181770549, COSV99992091; called by muse, mutect2, varscan2
- CDHR5 | c.2132C>A p.A711E (on ENST00000358353 / NM_001171968.2; = p.A717E on NM_021924.5) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV57641156; called by muse, mutect2, varscan2
- CEACAM21 | c.707A>G p.D236G (on ENST00000401445 / NM_001098506.4; = p.D235G on NM_033543.6) | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.168); catalogued as rs1555794395; called by muse, mutect2
- CEACAM6 | c.134T>C p.V45A | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as rs1555821101; called by muse, mutect2, varscan2
- CEBPB | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57277333; called by muse, mutect2, varscan2
- CELF3 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 157/650 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs375476666; called by muse, mutect2, varscan2
- CELSR1 | c.3605T>C p.M1202T | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs747369561; called by muse, mutect2
- CELSR1 | c.1115T>C p.V372A | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201491536; called by muse, mutect2, varscan2
- CELSR3 | c.6988C>T p.R2330C | Missense Mutation (SNP) | VAF 108/278 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs574950617; called by muse, mutect2, varscan2
- CENPJ | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV67884324; called by muse, varscan2
- CEP126 | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as COSV99680818; called by muse, mutect2, varscan2
- CEP170B | c.1466G>A p.R489H (on ENST00000453495; = p.R418H on NM_015005.3) | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1020511941; called by muse, mutect2, varscan2
- CEP250 | c.4762G>A p.V1588M | Missense Mutation (SNP) | VAF 123/318 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs144589737; called by muse, mutect2, varscan2
- CEP350 | c.1963A>G p.R655G | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1279961552; called by muse, mutect2, varscan2
- CERCAM | c.559del p.Q187Rfs*84 | Frame Shift Del (DEL) | VAF 42/125 reads (34%) | catalogued as rs780407630, COSV65712087; called by mutect2, varscan2
- CFAP44 | c.3122A>G p.H1041R | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs1430826982; called by muse, mutect2
- CFAP46 | c.6890C>T p.A2297V | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.198); catalogued as rs868840377; called by muse, mutect2, varscan2
- CFAP46 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 126/308 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs41302993, COSV63949155; called by muse, mutect2, varscan2
- CFAP54 | c.1926+2T>C p.X642_splice | Splice Site (SNP) | VAF 40/110 reads (36%) | catalogued as rs1177800822; called by muse, varscan2
- CFAP61 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 140/329 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1392638077; called by muse, mutect2, varscan2
- CFAP70 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.059); catalogued as COSV60284452; called by muse, mutect2, varscan2
- CHAC2 | c.508T>A p.L170I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.111); catalogued as rs769456826; called by muse, mutect2
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 84/308 reads (27%) | catalogued as rs747299117; called by mutect2, varscan2
- CHD5 | c.5182T>C p.S1728P | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.71); catalogued as rs1315600199; called by muse, mutect2, varscan2
- CHERP | c.1362dup p.W455Lfs*6 | Frame Shift Ins (INS) | VAF 61/170 reads (36%) | catalogued as rs770045437; called by mutect2, varscan2
- CHERP | c.1235A>C p.D412A | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV52225768; called by muse, mutect2, varscan2
- CHFR | c.1315G>A p.A439T (on ENST00000432561 / NM_001161345.1; = p.A398T on NM_018223.2) | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as rs1303770543; called by muse, mutect2, varscan2
- CHIC1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as rs1569498989, COSV65156161; called by mutect2, varscan2
- CHL1 | c.1768T>C p.C590R (on ENST00000397491 / NM_001253387.1; = p.C606R on NM_006614.4) | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1373684280; called by muse, mutect2, varscan2
- CHML | c.1829C>A p.P610H | Missense Mutation (SNP) | VAF 108/398 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100087051; called by muse, mutect2, varscan2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 56/140 reads (40%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRNA3 | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs1292414441; called by muse, mutect2, varscan2
- CHRNA7 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs1426386385; called by mutect2, varscan2
- CHST10 | c.56T>C p.M19T | Missense Mutation (SNP) | VAF 80/278 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as COSV99958858; called by muse, varscan2
- CHST2 | c.723dup p.R242Afs*92 | Frame Shift Ins (INS) | VAF 11/110 reads (10%) | catalogued as rs766570662; called by mutect2, pindel, varscan2
- CILP2 | c.245T>C p.F82S | Missense Mutation (SNP) | VAF 83/274 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99364415; called by muse, varscan2
- CILP2 | c.1736C>A p.A579E | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs199736818, COSV52273650, COSV52274070; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 29/74 reads (39%) | catalogued as rs752250702; called by mutect2, varscan2
- CLCA4 | c.819G>A p.W273* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as rs1475515437; called by muse, mutect2, varscan2
- CLCF1 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100425628; called by muse, mutect2, varscan2
- CLCN2 | c.774C>T p.G258= | Splice Region (SNP) | VAF 155/432 reads (36%) | catalogued as rs779280637; called by muse, mutect2, varscan2
- CLDN11 | c.574T>C p.Y192H | Missense Mutation (SNP) | VAF 34/526 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs762923439; called by muse, mutect2
- CLDN24 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 128/409 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs532949417; called by muse, mutect2, varscan2
- CLIC6 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1167342495; called by muse, mutect2, varscan2
- CLPTM1L | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 35/572 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329137218; called by muse, mutect2
- CLUH | c.1375T>C p.Y459H (on ENST00000435359; = p.Y497H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70929180; called by muse, mutect2, varscan2
- CMTM8 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.286); catalogued as rs926284606; called by muse, mutect2
- CNDP2 | c.457-2A>G p.X153_splice | Splice Site (SNP) | VAF 21/154 reads (14%) | catalogued as rs1169621623; called by muse, mutect2
- CNGA4 | c.272-2A>G p.X91_splice | Splice Site (SNP) | VAF 8/64 reads (13%) | catalogued as rs370207927; called by mutect2, varscan2
- CNN1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 124/357 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs368198606; called by muse, mutect2, varscan2
- CNNM1 | c.338del p.P113Rfs*121 | Frame Shift Del (DEL) | VAF 44/116 reads (38%) | catalogued as rs1368597633; called by mutect2, varscan2
- CNNM1 | c.1625A>G p.D542G | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1186598170; called by muse, mutect2
- CNNM2 | c.1037T>C p.V346A | Missense Mutation (SNP) | VAF 170/422 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.241); catalogued as rs1064794775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNPY4 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs751483119; called by muse, mutect2, varscan2
- CNR1 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV62986486; called by muse, mutect2, varscan2
- CNTN3 | c.3052A>G p.I1018V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1184313574; called by muse, mutect2, varscan2
- CNTN4 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761504879, COSV61877512; called by muse, mutect2, varscan2
- COG2 | c.906del p.G303Afs*11 | Frame Shift Del (DEL) | VAF 25/107 reads (23%) | catalogued as rs779434837; called by mutect2, pindel, varscan2
- COG3 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as COSV63072540; called by muse, mutect2
- COL11A1 | c.3977C>G p.A1326G | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV62186091; called by muse, mutect2, varscan2
- COL11A2 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 26/686 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1401298711; called by muse, mutect2
- COL18A1 | c.3911G>C p.G1304A (on ENST00000359759 / NM_130444.3; = p.G1069A on NM_030582.4) | Missense Mutation (SNP) | VAF 168/462 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV60594293; called by mutect2, varscan2
- COL1A1 | c.1936C>A p.P646T | Missense Mutation (SNP) | VAF 25/574 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1241546349; called by muse, mutect2
- COL23A1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 109/352 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs184713498; called by muse, mutect2, varscan2
- COL24A1 | c.654A>G p.I218M | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); catalogued as rs777200767; called by muse, mutect2, varscan2
- COL6A2 | c.2909T>A p.V970E | Missense Mutation (SNP) | VAF 15/318 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs1360530337; called by muse, mutect2
- COL6A5 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55213046; called by muse, mutect2, varscan2
- COL7A1 | c.7440+8T>C | Splice Region (SNP) | VAF 200/533 reads (38%) | catalogued as COSV100095754; called by muse, mutect2, varscan2
- COMP | c.677A>G p.Q226R | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.658); catalogued as COSV55875451; called by muse, mutect2, varscan2
- CPN1 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV100962542; called by muse, mutect2, varscan2
- CPNE2 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs912253609, COSV51963864; called by muse, mutect2
- CPSF1 | c.2788C>A p.R930S | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.383); catalogued as COSV99051586; called by muse, mutect2, varscan2
- CPSF6 | c.809_811del p.G270del | In Frame Del (DEL) | VAF 58/172 reads (34%) | catalogued as rs755559375; called by pindel, varscan2
- CPT1B | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 83/227 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780401114; called by muse, mutect2, varscan2
- CPT1C | c.884T>C p.L295S | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.156); catalogued as rs764608433; called by muse, mutect2, varscan2
- CRACD | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.054); catalogued as COSV51731125, COSV51731697; called by muse, mutect2, varscan2
- CREBBP | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 101/303 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); catalogued as rs1311466278, COSV52113306; called by muse, mutect2, varscan2
- CRHR1 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 82/210 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.842); catalogued as rs942722884; called by muse, mutect2, varscan2
- CRIM1 | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 58/160 reads (36%) | catalogued as COSV54874556; called by muse, mutect2, varscan2
- CRNN | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 97/383 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.153); catalogued as rs564062937; called by muse, mutect2, varscan2
- CROCC | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 190/696 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as rs755127984, COSV65010352; called by muse, mutect2, varscan2
- CROT | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs1377919834; called by muse, mutect2, varscan2
- CRTAC1 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs201812545; called by muse, mutect2, varscan2
- CSF2RA | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 164/464 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as rs1186460962, COSV100817793; called by muse, mutect2, varscan2
- CSNK1G3 | c.340A>G p.M114V | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as rs780897570; called by muse, mutect2, varscan2
- CSTF1 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53860825; called by muse, mutect2, varscan2
- CTAGE1 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 33/669 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs1480064296, COSV66944540; called by muse, mutect2
- CTNNA3 | c.1958C>T p.T653I | Missense Mutation (SNP) | VAF 82/233 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV65620925; called by muse, mutect2, varscan2
- CTNND2 | c.3542C>T p.P1181L | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1292653848; called by muse, mutect2, varscan2
- CTSF | c.1211T>C p.I404T | Missense Mutation (SNP) | VAF 140/433 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1296401147; called by muse, mutect2, varscan2
- CWF19L2 | c.1654G>C p.D552H | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56515241; called by muse, mutect2
- CYLC2 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs761244512; called by muse, mutect2, varscan2
- CYP26C1 | c.1435A>G p.T479A | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as rs777493031; called by muse, mutect2, varscan2
- CYP2F1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 122/311 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs950111044, COSV58526794; called by muse, mutect2, varscan2
- CYP2W1 | c.689A>G p.H230R | Missense Mutation (SNP) | VAF 126/374 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as rs777113335; called by muse, varscan2
- CYP4B1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as rs1330969028, COSV54724490; called by muse, mutect2, varscan2
- DAG1 | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 76/546 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.266); catalogued as rs1478739954; called by muse, varscan2
- DAXX | c.1466-1G>A p.X489_splice | Splice Site (SNP) | VAF 38/90 reads (42%) | catalogued as rs1217383193; called by muse, mutect2, varscan2
- DCAF13 | c.449T>C p.L150S | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs781010399; called by muse, mutect2, varscan2
- DCBLD2 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1010944678; called by muse, mutect2, varscan2
- DCC | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 53/433 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1306181734; called by muse, mutect2, varscan2
- DDI2 | c.632+4A>G | Splice Region (SNP) | VAF 10/167 reads (6%) | catalogued as rs1267053826; called by muse, mutect2
- DDX19A | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 125/313 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.039); catalogued as rs773132234; called by muse, mutect2, varscan2
- DDX19B | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs751106898, COSV55364617; called by muse, mutect2, varscan2
- DDX50 | c.1337A>G p.N446S | Missense Mutation (SNP) | VAF 110/282 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as rs1214872571; called by muse, mutect2, varscan2
- DDX60L | c.2132T>C p.I711T | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as rs1228085944; called by muse, mutect2, varscan2
- DEFA3 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 160/538 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.094); catalogued as rs1348084814, COSV100590681; called by muse, mutect2, varscan2
- DEFB106A | c.66dup p.D23* | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | catalogued as rs780992152; called by mutect2, varscan2
- DEGS2 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1415703661; called by muse, mutect2
- DENND2B | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs368147762; called by muse, varscan2
- DENND3 | c.2870A>T p.N957I | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV99370887; called by muse, mutect2, varscan2
- DENND5A | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs148317700; called by muse, mutect2, varscan2
- DEUP1 | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 101/223 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV53209696, COSV53213827; called by muse, mutect2, varscan2
- DEUP1 | c.673T>C p.F225L | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs764802469, COSV53217585; called by muse, mutect2, varscan2
- DGKH | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs766095835, COSV54929295; called by muse, mutect2, varscan2
- DHCR7 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs1330568278; called by muse, mutect2, varscan2
- DHRS4 | c.625T>G p.C209G | Missense Mutation (SNP) | VAF 92/269 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as rs771903144; called by muse, mutect2, varscan2
- DHRS7B | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs770787003, COSV60887885; called by muse, mutect2, varscan2
- DHX34 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 105/321 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs749308881; called by muse, mutect2, varscan2
- DHX8 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 113/281 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs777020341, COSV52255555; called by muse, mutect2, varscan2
- DIDO1 | c.6379C>T p.R2127W | Missense Mutation (SNP) | VAF 142/395 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1382659781, COSV99825725; called by muse, mutect2, varscan2
- DIDO1 | c.6101del p.P2034Rfs*240 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | catalogued as COSV56634983; called by mutect2, pindel, varscan2
- DIDO1 | c.5234del p.G1745Afs*119 | Frame Shift Del (DEL) | VAF 88/259 reads (34%) | catalogued as COSV99825386; called by mutect2, pindel, varscan2
- DIO2 | c.788G>A p.S263N | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101375840; called by muse, mutect2
- DLG5 | c.5465C>T p.P1822L | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.705); catalogued as rs931692281, COSV100967436; called by muse, mutect2, varscan2
- DLGAP3 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.046); catalogued as rs747689409, COSV52395602; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 108/158 reads (68%) | catalogued as rs762874947; called by mutect2, varscan2
- DLGAP4 | c.682A>G p.M228V | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV59420157; called by muse, mutect2, varscan2
- DLL1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 190/508 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs779478084; called by muse, mutect2, varscan2
- DMAC2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1555769994, COSV55729245; called by muse, mutect2, varscan2
- DMD | c.9564-2A>G p.X3188_splice | Splice Site (SNP) | VAF 78/259 reads (30%) | catalogued as CS046009; called by muse, mutect2, varscan2
- DMXL1 | c.6772A>G p.N2258D | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV60715989; called by muse, mutect2, varscan2
- DNAAF5 | c.1093T>C p.C365R | Missense Mutation (SNP) | VAF 145/371 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1305239396; called by muse, mutect2, varscan2
- DNAH1 | c.6250C>T p.P2084S | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs748501791; called by muse, mutect2, varscan2
- DNAH1 | c.7204G>C p.A2402P | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.776); catalogued as COSV70233198; called by muse, mutect2, varscan2
- DNAH10 | c.4108C>T p.P1370S (on ENST00000409039; = p.P1309S on NM_207437.3) | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as rs763449366, COSV68999810; called by muse, mutect2, varscan2
- DNAH10 | c.5998G>A p.A2000T (on ENST00000409039; = p.A1939T on NM_207437.3) | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs767489276; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 46/116 reads (40%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH14 | c.2414C>T p.A805V (on ENST00000445597; = p.A871V on NM_001367479.1) | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as COSV60742631; called by muse, mutect2, varscan2
- DNAH17 | c.5272A>G p.T1758A | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101103018; called by muse, mutect2, varscan2
- DNAH7 | c.3221dup p.L1074Ffs*4 | Frame Shift Ins (INS) | VAF 42/134 reads (31%) | catalogued as rs763352877; called by mutect2, varscan2
- DNAH7 | c.2478del p.V827* | Frame Shift Del (DEL) | VAF 66/202 reads (33%) | catalogued as rs752238407, COSV56751321; called by mutect2, pindel, varscan2
- DNAH8 | c.9103G>A p.A3035T | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100543116; called by muse, mutect2, varscan2
- DNAI4 | c.1834A>G p.I612V | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs908121315, COSV64021409; called by muse, mutect2, varscan2
- DNAJC28 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 43/138 reads (31%) | catalogued as COSV58721991; called by muse, mutect2, varscan2
- DNHD1 | c.4714A>G p.S1572G | Missense Mutation (SNP) | VAF 116/289 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.31); catalogued as rs1179981841; called by muse, mutect2, varscan2
- DNHD1 | c.10625G>A p.R3542Q | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs778180519, COSV54436638; called by muse, mutect2, varscan2
- DNMT3L | c.516G>A p.S172= | Splice Region (SNP) | VAF 22/178 reads (12%) | catalogued as rs372192557; called by muse, varscan2
- DOCK11 | c.1778T>C p.V593A | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs747351180; called by muse, mutect2, varscan2
- DOCK4 | c.5306G>T p.S1769I | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as rs1243755650; called by muse, mutect2
- DOK1 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 122/335 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV51212906; called by muse, mutect2, varscan2
- DOK3 | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1382841676; called by muse, mutect2, varscan2
- DOK6 | c.579G>A p.W193* | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | catalogued as COSV101234907, COSV66926316; called by muse, mutect2, varscan2
- DONSON | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.04); catalogued as rs898637106; called by muse, mutect2, varscan2
- DPP7 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368784110; called by muse, mutect2, varscan2
- DPPA2 | c.431A>G p.Q144R | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.388); catalogued as COSV72118297; called by muse, mutect2
- DPY19L1 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1274870392; called by muse, mutect2
- DPY19L3 | c.918del p.F306Lfs*4 | Frame Shift Del (DEL) | VAF 56/196 reads (29%) | catalogued as rs776782588; called by pindel, varscan2
- DRC7 | c.986G>A p.S329N | Missense Mutation (SNP) | VAF 28/459 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); catalogued as rs1380668543; called by muse, mutect2
- DROSHA | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as rs746400926; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs750962255; called by mutect2, varscan2
- DUOX2 | c.2598G>A p.M866I | Missense Mutation (SNP) | VAF 77/657 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101199798; called by muse, mutect2, varscan2
- DUSP16 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as rs1320499832; called by muse, varscan2
- DYNC1H1 | c.6320G>A p.R2107K | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV100794349; called by muse, mutect2, varscan2
- DYNC1H1 | c.7000A>G p.S2334G | Missense Mutation (SNP) | VAF 216/521 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV64139844; called by muse, mutect2, varscan2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs768937539; called by mutect2, pindel, varscan2
- DZIP1L | c.1472T>C p.L491P | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1183044204; called by muse, mutect2, varscan2
- E2F3 | c.254_256del p.L85del | In Frame Del (DEL) | VAF 118/348 reads (34%) | catalogued as rs757483296; called by pindel, varscan2
- EBF4 | c.481A>G p.M161V (on ENST00000609451; = p.M157V on NM_001110514.1) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs770070084; called by muse, mutect2, varscan2
- ECEL1 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 308/788 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs766643692, COSV100458510; called by muse, mutect2, varscan2
- EFCAB13 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1415674575; called by muse, mutect2, varscan2
- EFCAB6 | c.3895A>G p.T1299A | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1440927523; called by muse, mutect2, varscan2
- EFL1 | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV51605999; called by muse, mutect2, varscan2
- EFNA4 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 22/141 reads (16%) | catalogued as rs760012398, COSV100699633; called by muse, mutect2, varscan2
- EFS | c.1573G>T p.A525S | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1040172271; called by muse, mutect2, varscan2
- EGF | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 132/351 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs773442580; called by muse, mutect2, varscan2
- EHBP1L1 | c.3944C>T p.A1315V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs201994053; called by muse, mutect2, varscan2
- EHBP1L1 | c.4561G>A p.V1521M | Missense Mutation (SNP) | VAF 108/260 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1479923557; called by muse, mutect2, varscan2
- EIF2AK2 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs560003765; called by muse, mutect2, varscan2
- EIF2S1 | c.911A>G p.D304G | Missense Mutation (SNP) | VAF 40/493 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53606699; called by muse, mutect2
- EIF3K | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV50264742; called by muse, mutect2
- ELFN1 | c.2044A>G p.T682A | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as rs749201685; called by muse, varscan2
- ELFN1 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV70035889; called by muse, varscan2
- EML6 | c.2923A>G p.T975A | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1208321903; called by muse, mutect2, varscan2
- EML6 | c.3263T>A p.I1088N | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100728886; called by muse, mutect2, varscan2
- ENC1 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as rs750885340; called by muse, mutect2
- ENPP5 | c.977T>A p.I326N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57908717; called by muse, mutect2, varscan2
- ENTHD1 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV100288365; called by muse, mutect2, varscan2
- ENTPD8 | c.777del p.L260Wfs*40 | Frame Shift Del (DEL) | VAF 55/200 reads (28%) | catalogued as rs774455783; called by mutect2, pindel, varscan2
- EPB42 | c.920A>G p.Y307C (on ENST00000441366 / NM_001114134.2; = p.Y337C on NM_000119.3) | Missense Mutation (SNP) | VAF 164/407 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs779817358; called by muse, mutect2, varscan2
- EPHB6 | c.165+1dup | Frame Shift Ins (INS) | VAF 82/398 reads (21%) | catalogued as rs771807343; called by mutect2, varscan2
- EPHB6 | c.2507A>G p.H836R | Missense Mutation (SNP) | VAF 62/501 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as rs766835497; called by muse, mutect2, varscan2
- ERBB3 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs892530465; called by muse, mutect2, varscan2
- ERBB3 | c.1763G>A p.S588N | Missense Mutation (SNP) | VAF 66/561 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV57262300; called by muse, mutect2, varscan2
- ERCC2 | c.2024G>A p.G675D | Missense Mutation (SNP) | VAF 260/725 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67268033; called by muse, mutect2, varscan2
- ERG | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 21/355 reads (6%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as COSV101296397, COSV67364227; called by muse, mutect2
- ERO1B | c.750A>G p.I250M | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1409235568; called by muse, mutect2, varscan2
- ESRP2 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs754097001, COSV52173501; called by muse, mutect2, varscan2
- ESRRG | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 127/459 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV63156141; called by muse, mutect2, varscan2
- ESX1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 86/287 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV65423807; called by muse, mutect2, varscan2
- ETV6 | c.613del p.L205Wfs*4 | Frame Shift Del (DEL) | VAF 94/271 reads (35%) | catalogued as rs1232497641; called by mutect2, pindel, varscan2
- EVI5 | c.1222del p.M408* | Frame Shift Del (DEL) | VAF 30/66 reads (45%) | catalogued as rs760182064; called by mutect2, varscan2
- EVPL | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs1335825167; called by muse, varscan2
- EXOSC10 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs760329299; called by muse, mutect2
- EXT1 | c.1332A>G p.I444M | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs531329914; called by muse, varscan2
- EXT1 | c.962+1G>A p.X321_splice | Splice Site (SNP) | VAF 109/331 reads (33%) | catalogued as CS042161, CS054188, CS099207, COSV65482409; called by muse, mutect2, varscan2
- FAM118A | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 149/402 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as rs757022752; called by muse, mutect2, varscan2
- FAM135B | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV99418899; called by muse, varscan2
- FAM135B | c.1399C>A p.P467T | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as COSV52737874; called by muse, mutect2, varscan2
- FAM155B | c.1165T>C p.S389P | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.81); catalogued as rs1186746792; called by muse, mutect2, varscan2
- FAM171A2 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs1468077016; called by muse, varscan2
- FAM177A1 | c.104A>T p.N35I (on ENST00000382406 / NM_001289022.2; = p.N58I on NM_173607.5) | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as rs139599306; called by muse, varscan2
- FAM181B | c.339del p.G114Afs*80 | Frame Shift Del (DEL) | VAF 48/170 reads (28%) | catalogued as rs1555002816, COSV100235053; called by mutect2, pindel, varscan2
- FAM200B | c.1304T>A p.I435N | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759753106; called by muse, mutect2
- FAM205A | c.3229C>T p.R1077C | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs766450365, COSV66488543; called by muse, mutect2, varscan2
- FAM214A | c.2042dup p.N681Kfs*2 | Frame Shift Ins (INS) | VAF 28/108 reads (26%) | catalogued as rs762546731; called by mutect2, varscan2
- FAM227B | c.645+3A>G | Splice Region (SNP) | VAF 14/92 reads (15%) | catalogued as rs1356031264; called by muse, mutect2, varscan2
- FAM27E5 | n.278+2T>C | Splice Site (SNP) | VAF 52/119 reads (44%) | catalogued as rs751652942; called by muse, mutect2
- FAM83E | c.391T>C p.Y131H | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV99320256; called by muse, mutect2, varscan2
- FAM83H | c.3346C>T p.R1116C | Missense Mutation (SNP) | VAF 27/474 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs781902109; called by muse, mutect2
- FAT3 | c.3581A>T p.N1194I | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565383654, COSV53118407; called by muse, mutect2
- FAT3 | c.8786A>G p.Y2929C | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs773636509; called by muse, mutect2, varscan2
- FAT3 | c.11035A>G p.T3679A | Missense Mutation (SNP) | VAF 92/243 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.099); catalogued as rs1391242727; called by muse, mutect2, varscan2
- FAT3 | c.12715C>T p.P4239S | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs948202155; called by muse, mutect2
- FBRSL1 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 89/288 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55518484; called by muse, mutect2, varscan2
- FBXL18 | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs753869482; called by muse, mutect2
- FBXO21 | c.432dup p.E145* | Frame Shift Ins (INS) | VAF 74/126 reads (59%) | catalogued as rs772635228; called by mutect2, varscan2
- FBXO3 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as rs746467667, COSV55764998; called by muse, mutect2, varscan2
- FCHO1 | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs201051085; called by muse, mutect2, varscan2
- FER1L6 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as rs1167415509; called by muse, mutect2, varscan2
- FGD2 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV99236481; called by muse, mutect2
- FGL2 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 118/288 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1016961575; called by muse, mutect2, varscan2
- FHL1 | c.501+2T>C p.X167_splice | Splice Site (SNP) | VAF 130/313 reads (42%) | catalogued as rs113036778; called by muse, mutect2, varscan2
- FHOD1 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as rs748329982; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | catalogued as rs777980924; called by mutect2, pindel
- FIGN | c.1502A>G p.E501G | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs748727733; called by muse, mutect2, varscan2
- FLNA | c.3049C>G p.P1017A | Missense Mutation (SNP) | VAF 77/543 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as CD092208, COSV61048621; called by muse, mutect2, varscan2
- FLNC | c.4379G>A p.R1460Q | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs773716930; called by muse, mutect2, varscan2
- FLOT1 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 143/408 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.268); catalogued as rs747028837; called by muse, mutect2, varscan2
- FMN2 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs1317589828, COSV100145126; called by muse, mutect2, varscan2
- FMN2 | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60432582; called by muse, mutect2
- FMO4 | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.108); catalogued as COSV100882173; called by muse, mutect2, varscan2
- FNDC1 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs762902369, COSV51929688; called by muse, mutect2, varscan2
- FNDC3B | c.973C>G p.R325G | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV61037308, COSV61041242; called by muse, mutect2, varscan2
- FNIP1 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.55); catalogued as rs774812138; called by muse, mutect2, varscan2
- FOXA1 | c.1417T>C p.*473Qext*34 | Nonstop Mutation (SNP) | VAF 49/485 reads (10%) | catalogued as COSV51646683; called by muse, mutect2
- FOXC1 | c.179T>C p.M60T | Missense Mutation (SNP) | VAF 33/502 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1310279713; called by muse, mutect2
- FOXC2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs769190596; called by muse, mutect2, varscan2
- FOXD2 | c.112dup p.E38Gfs*454 | Frame Shift Ins (INS) | VAF 32/99 reads (32%) | catalogued as rs1557455762; called by mutect2, varscan2
- FOXL1 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57214647; called by muse, mutect2
- FOXL2NB | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 117/352 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs1000923858; called by muse, mutect2, varscan2
- FRMD5 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 127/329 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV68721180; called by muse, mutect2, varscan2
- FUT1 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV59567734; called by muse, mutect2
- FUT11 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as rs371592507; called by muse, mutect2, varscan2
- FZD3 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.669); catalogued as COSV53534291; called by muse, varscan2
- GAL3ST1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100143000; called by muse, varscan2
- GALE | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 262/835 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as rs201455293; called by muse, mutect2, varscan2
- GALNT2 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 110/416 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV64196608; called by muse, mutect2, varscan2
- GAR1 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.999); catalogued as rs202241831; called by muse, mutect2, varscan2
- GAREM2 | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV66108590; called by muse, mutect2, varscan2
- GBP4 | c.1789del p.I597Lfs*9 | Frame Shift Del (DEL) | VAF 23/201 reads (11%) | catalogued as COSV63254146; called by mutect2, pindel, varscan2
- GCC2 | c.4986T>C p.G1662= | Splice Region (SNP) | VAF 78/238 reads (33%) | catalogued as rs780774991; called by muse, mutect2, varscan2
- GCNT4 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59280438; called by muse, mutect2, varscan2
- GDF15 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 80/232 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.191); catalogued as rs749673730; called by muse, mutect2, varscan2
- GDNF | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 27/307 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs904134315; called by muse, mutect2
- GEMIN5 | c.3110G>A p.G1037D | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs765730393; called by muse, mutect2, varscan2
- GGA3 | c.1562A>G p.Q521R (on ENST00000537686 / NM_138619.4; = p.Q488R on NM_014001.5) | Missense Mutation (SNP) | VAF 148/446 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as rs1368959837; called by muse, mutect2, varscan2
- GGT7 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV60540219; called by muse, mutect2, varscan2
- GHSR | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 142/388 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as rs777777248, COSV53840536; called by muse, mutect2, varscan2
- GIGYF1 | c.2342G>A p.G781D | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs1275344315; called by muse, mutect2
- GIMAP2 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56236284; called by muse, mutect2, varscan2
- GJA3 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 130/354 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1292275593, COSV99576450; called by muse, mutect2, varscan2
- GLB1 | c.574T>C p.Y192H | Missense Mutation (SNP) | VAF 107/308 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1408171481, CM165998; called by muse, mutect2, varscan2
- GLIPR2 | c.228A>G p.G76= | Splice Region (SNP) | VAF 12/79 reads (15%) | catalogued as rs1457718919; called by muse, mutect2, varscan2
- GLIS3 | c.1517del p.K506Sfs*145 | Frame Shift Del (DEL) | VAF 111/375 reads (30%) | catalogued as COSV100173970; called by mutect2, pindel, varscan2
- GLRX3 | c.276+1G>A p.X92_splice | Splice Site (SNP) | VAF 24/58 reads (41%) | catalogued as COSV58691719; called by muse, mutect2, varscan2
- GNA12 | c.262A>C p.K88Q | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1404261944; called by muse, mutect2, varscan2
- GNAS | c.1817A>G p.N606S | Missense Mutation (SNP) | VAF 392/995 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.264); catalogued as COSV100007985; called by muse, mutect2, varscan2
- GOLGA8J | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as rs1447359188; called by mutect2, varscan2
- GOLGA8M | c.1472A>G p.K491R | Missense Mutation (SNP) | VAF 199/599 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.09); catalogued as rs1206881900; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | catalogued as rs370114090; called by mutect2, varscan2
- GP9 | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as CD058322; called by muse, mutect2
- GPC4 | c.1290C>A p.S430R | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV63698044; called by muse, mutect2, varscan2
- GPLD1 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as rs772269151; called by muse, mutect2, varscan2
- GPR101 | c.72G>T p.M24I | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1470717869; called by muse, mutect2, varscan2
- GPR149 | c.677A>G p.H226R | Missense Mutation (SNP) | VAF 103/260 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs768614338; called by muse, mutect2, varscan2
- GPR39 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 167/435 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61428729; called by muse, mutect2, varscan2
- GPR78 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763140925; called by muse, mutect2, varscan2
- GPT | c.1235T>C p.M412T | Missense Mutation (SNP) | VAF 57/674 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs376611071; called by muse, mutect2
- GREB1 | c.2915C>T p.A972V | Missense Mutation (SNP) | VAF 179/487 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV52194896; called by muse, mutect2, varscan2
- GRIA4 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 139/396 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0.026); catalogued as COSV99230499; called by muse, mutect2, varscan2
- GRIN1 | c.655A>T p.I219F | Missense Mutation (SNP) | VAF 218/581 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs1356531038; called by muse, mutect2, varscan2
- GRIN2B | c.1535C>T p.S512L | Missense Mutation (SNP) | VAF 182/504 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV74208475; called by muse, mutect2, varscan2
- GRIN2B | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV74204839, COSV74205379; called by muse, mutect2, varscan2
- GRM1 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 50/504 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51371869; called by muse, mutect2
- GRM3 | c.676G>T p.G226W | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64468915; called by muse, mutect2
- GRM6 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99179798; called by muse, mutect2, varscan2
- GRM8 | c.80T>C p.M27T | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58809591; called by muse, mutect2, varscan2
- GRN | c.138+8C>T | Splice Region (SNP) | VAF 60/448 reads (13%) | catalogued as rs764388805; called by muse, mutect2, varscan2
- GRXCR1 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.622); catalogued as rs1285589545; called by muse, mutect2, varscan2
- GSDMC | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV52697631, COSV52698409; called by muse, mutect2, varscan2
- GSR | c.907T>C p.S303P | Missense Mutation (SNP) | VAF 190/501 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1303461733; called by muse, mutect2, varscan2
- GSX2 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 23/309 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1560410902; called by muse, mutect2
- GTF3C4 | c.1691del p.K564Rfs*18 | Frame Shift Del (DEL) | VAF 77/223 reads (35%) | catalogued as rs1241168444, COSV64645321; called by mutect2, pindel, varscan2
- GTPBP2 | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100199862; called by muse, mutect2, varscan2
- GUCY2C | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs777915367; called by muse, mutect2, varscan2
- GYG2 | c.448A>G p.R150G | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1051778653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GYG2 | c.680T>C p.M227T | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1194281782; called by muse, mutect2, varscan2
- H1-5 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 220/534 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1438194143; called by muse, mutect2, varscan2
- H2BC14 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 127/322 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV100297538, COSV60797646; called by muse, mutect2, varscan2
- H3C1 | c.109A>G p.K37E | Missense Mutation (SNP) | VAF 134/378 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV55120385; called by muse, mutect2, varscan2
- H4C5 | c.77A>G p.N26S | Missense Mutation (SNP) | VAF 103/247 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as COSV63486953; called by muse, mutect2, varscan2
- HACE1 | c.1678+2T>C p.X560_splice | Splice Site (SNP) | VAF 143/390 reads (37%) | catalogued as COSV53503238; called by muse, mutect2, varscan2
- HACE1 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.973); catalogued as rs1441448408; called by muse, mutect2, varscan2
- HAO1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 186/484 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1167177393; called by muse, mutect2, varscan2
- HAPLN1 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs765478241, COSV99164703; called by muse, mutect2, varscan2
- HAS1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV55787516; called by muse, mutect2
- HBA1 | c.50del p.K17Rfs*33 | Frame Shift Del (DEL) | VAF 75/358 reads (21%) | catalogued as CM139990; called by mutect2, varscan2
- HBG2 | c.200A>G p.K67R | Missense Mutation (SNP) | VAF 74/1122 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs35481866; ClinVar: other; called by muse, mutect2
- HCFC1 | c.3436G>A p.V1146M | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.09); catalogued as rs781984758; called by muse, mutect2, varscan2
- HCN2 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 191/483 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.329); catalogued as rs747888265, COSV52116840; called by muse, varscan2
- HCN4 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.459); catalogued as rs1432580542; called by muse, varscan2
- HEATR5A | c.1421A>G p.H474R | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs930578577; called by muse, mutect2
- HECTD1 | c.3100T>C p.Y1034H | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as rs1203966015; called by muse, mutect2
- HECTD4 | c.8932A>G p.I2978V | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as COSV66388071; called by muse, mutect2
- HECW1 | c.1703A>G p.H568R | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs1404597417; called by muse, mutect2
- HERC5 | c.2354A>C p.N785T | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV52038758; called by muse, mutect2, varscan2
- HGFAC | c.246del p.L83Sfs*164 | Frame Shift Del (DEL) | VAF 17/41 reads (41%) | catalogued as rs1220870213; called by mutect2, pindel, varscan2
- HHIPL2 | c.1240T>C p.Y414H | Missense Mutation (SNP) | VAF 128/489 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs765169449; called by muse, mutect2, varscan2
- HIC2 | c.1250dup p.S418Qfs*38 | Frame Shift Ins (INS) | VAF 54/150 reads (36%) | catalogued as rs1568944577; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- HIP1R | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as rs140741256; called by muse, mutect2, varscan2
- HIVEP3 | c.6817del p.D2273Tfs*209 | Frame Shift Del (DEL) | VAF 126/320 reads (39%) | catalogued as rs753412359; called by mutect2, pindel, varscan2
- HK3 | c.1954-1G>A p.X652_splice | Splice Site (SNP) | VAF 60/138 reads (43%) | catalogued as COSV99459474; called by muse, mutect2, varscan2
- HLX | c.1135A>G p.S379G | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1365163512; called by muse, varscan2
- HMGN5 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as rs374413319; called by muse, mutect2
- HNRNPA2B1 | c.367A>G p.T123A (on ENST00000354667 / NM_031243.3; = p.T111A on NM_002137.4) | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as COSV100522937; called by muse, mutect2, varscan2
- HNRNPF | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV61561506; called by muse, mutect2, varscan2
- HNRNPK | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100698891; called by muse, mutect2, varscan2
- HOXA3 | c.138C>A p.H46Q | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs373369365; called by muse, mutect2, varscan2
- HOXB2 | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1187454907; called by muse, mutect2
- HRCT1 | c.149del p.G50Efs*108 | Frame Shift Del (DEL) | VAF 84/307 reads (27%) | catalogued as rs763549083; called by pindel, varscan2
- HSPG2 | c.3818T>C p.I1273T | Missense Mutation (SNP) | VAF 54/755 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs148626419; called by muse, mutect2
- HTATSF1 | c.128A>G p.Q43R | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs1375893480; called by muse, mutect2, varscan2
- HTT | c.6935A>G p.H2312R | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773344648; called by muse, mutect2
- ICE1 | c.1874A>G p.D625G | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56825436; called by muse, mutect2, varscan2
- IDH2 | c.435dup p.T146Dfs*126 | Frame Shift Ins (INS) | VAF 208/626 reads (33%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 82/235 reads (35%) | catalogued as rs750779916, COSV60737300; called by mutect2, varscan2
- IFI16 | c.393dup p.S132Ifs*12 | Frame Shift Ins (INS) | VAF 16/126 reads (13%) | catalogued as rs750703064; called by mutect2, varscan2
- IFT140 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV68487314; called by muse, mutect2
- IGDCC4 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768965705; called by muse, mutect2, varscan2
- IGF1R | c.3866A>G p.E1289G | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); catalogued as rs747754427; called by muse, mutect2, varscan2
- IGHG1 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 119/333 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1289644606; called by muse, mutect2, varscan2
- IGHV4-59 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 226/1402 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs781864329; called by muse, varscan2
- IGSF9 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs1408084829; called by muse, mutect2
- IGSF9B | c.3325G>A p.G1109S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.006); catalogued as COSV100317953; called by muse, varscan2
- IKBIP | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs201420285; called by muse, mutect2, varscan2
- IL12RB2 | c.1372T>C p.W458R | Missense Mutation (SNP) | VAF 198/491 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1310985326; called by muse, mutect2, varscan2
- IL13RA1 | c.697A>G p.I233V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV65426247; called by muse, mutect2, varscan2
- IL1RAP | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs750808388; called by muse, mutect2, varscan2
- IL1RL2 | c.1680C>T p.G560= | Splice Region (SNP) | VAF 44/125 reads (35%) | catalogued as rs1468948006; called by muse, mutect2, varscan2
- IL21R | c.1549del p.R517Gfs*38 | Frame Shift Del (DEL) | VAF 57/208 reads (27%) | catalogued as rs748992699; called by pindel, varscan2
- IL27RA | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 136/364 reads (37%) | catalogued as rs1459947831, COSV54601450, COSV54603418; called by muse, mutect2, varscan2
- ING5 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as COSV57978616; called by muse, mutect2
- INO80 | c.3635G>A p.R1212H | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62736017, COSV62736223; called by muse, mutect2, varscan2
- INPP5J | c.868A>G p.S290G | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs1224700070; called by muse, mutect2
- INPPL1 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 113/319 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.62); catalogued as rs373511105; called by muse, mutect2, varscan2
- INPPL1 | c.2927dup p.P977Tfs*7 | Frame Shift Ins (INS) | VAF 23/56 reads (41%) | catalogued as rs749079348; called by mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 35/104 reads (34%) | catalogued as rs760925109; called by mutect2, varscan2
- IPO13 | c.2857G>A p.G953S | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV54837153, COSV54838881; called by muse, mutect2
- IPO7 | c.2476G>A p.D826N | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101121797; called by muse, varscan2
- IQCA1 | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 137/387 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs757468336; called by muse, mutect2, varscan2
- IQCE | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372817817, COSV58077395; called by muse, mutect2, varscan2
- IQCK | c.481A>G p.R161G | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs773849654; called by muse, mutect2, varscan2
- IRAK2 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 169/470 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as rs1445903544; called by muse, mutect2, varscan2
- IRGC | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs758334834, COSV54982707; called by muse, mutect2, varscan2
- IRGQ | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 98/308 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs759278713; called by muse, mutect2, varscan2
- IRS2 | c.3272dup p.K1092Efs*233 | Frame Shift Ins (INS) | VAF 52/163 reads (32%) | catalogued as rs772322568; called by mutect2, varscan2
- IRS4 | c.2603G>A p.G868E | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV64532958; called by muse, mutect2
- IRS4 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 162/438 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV64535694; called by muse, mutect2, varscan2
- ITGA10 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 184/505 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.773); catalogued as rs782136957; called by muse, mutect2, varscan2
- ITGA4 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV51997588; called by muse, mutect2, varscan2
- ITGAV | c.1682dup p.L562Tfs*5 | Frame Shift Ins (INS) | VAF 26/65 reads (40%) | catalogued as rs1209653205; called by mutect2, varscan2
- ITPRID1 | c.25T>A p.S9T | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.445); catalogued as rs1174486498; called by muse, mutect2, varscan2
- IVL | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 32/419 reads (8%) | catalogued as rs1203503868; called by muse, mutect2
- JADE2 | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs763222107; called by muse, mutect2, varscan2
- JAG2 | c.3143C>T p.A1048V | Missense Mutation (SNP) | VAF 165/438 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as rs1487821709, COSV59305982; called by muse, mutect2, varscan2
- JAKMIP2 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs772282484; called by muse, mutect2, varscan2
- JMJD4 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 29/114 reads (25%) | catalogued as rs745572833; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.501); catalogued as rs745405146; called by muse, mutect2, varscan2
- JUN | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs1428182696; called by muse, mutect2, varscan2
- KAT6B | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 155/457 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs774022852; called by muse, mutect2, varscan2
- KATNAL2 | c.1552A>G p.K518E (on ENST00000356157 / NM_001353899.1; = p.K446E on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/280 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99797196; called by muse, mutect2, varscan2
- KATNIP | c.2383G>A p.G795S | Missense Mutation (SNP) | VAF 32/339 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs200901038; called by muse, mutect2
- KAZALD1 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1564656561, COSV64630000; called by muse, mutect2, varscan2
- KCNA3 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs764269530, COSV100871182; called by muse, mutect2, varscan2
- KCNC3 | c.1880del p.G627Efs*27 | Frame Shift Del (DEL) | VAF 48/127 reads (38%) | catalogued as rs1159900432; called by mutect2, pindel, varscan2
- KCND2 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV58572983; called by muse, mutect2, varscan2
- KCNG1 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857093; called by muse, mutect2, varscan2
- KCNG1 | c.492C>G p.C164W | Missense Mutation (SNP) | VAF 169/420 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65367981; called by muse, mutect2, varscan2
- KCNJ12 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 94/440 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs367663948; called by muse, mutect2, varscan2
- KCNJ5 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 153/382 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV57966219; called by muse, mutect2, varscan2
- KCNK7 | c.692A>G p.Y231C | Missense Mutation (SNP) | VAF 110/317 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs559187716; called by muse, mutect2, varscan2
- KCNK7 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 38/356 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs369551762; called by muse, mutect2
- KCNS2 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54638711; called by muse, mutect2, varscan2
- KCNT1 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1434362639; called by muse, mutect2, varscan2
- KCNV2 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 190/525 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs962085824; called by muse, mutect2, varscan2
- KDELR3 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 43/551 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1363738550; called by muse, mutect2
- KDM1B | c.1133del p.K378Rfs*18 (on ENST00000449850; = p.K246Rfs*18 on NM_153042.4) | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | catalogued as COSV52809203; called by pindel, varscan2
- KDM2B | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 170/469 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100997383, COSV65638103; called by muse, mutect2, varscan2
- KDM5B | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 99/325 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199931893; called by muse, mutect2, varscan2
- KDM5C | c.4286del p.P1429Qfs*49 | Frame Shift Del (DEL) | VAF 192/597 reads (32%) | catalogued as COSV64767609; called by mutect2, pindel, varscan2
- KDM6B | c.3274C>A p.L1092M | Missense Mutation (SNP) | VAF 15/318 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.344); catalogued as COSV99642685; called by muse, mutect2
- KIAA0100 | c.6275G>A p.R2092H | Missense Mutation (SNP) | VAF 92/260 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747853930; called by muse, mutect2, varscan2
- KIAA0100 | c.2477T>C p.V826A | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.076); catalogued as rs1257938763; called by muse, mutect2, varscan2
- KIAA0100 | c.1463A>G p.N488S | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.084); catalogued as rs1222101305, COSV66490765; called by muse, mutect2, varscan2
- KIAA1217 | c.2510A>G p.Y837C | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56814775; called by muse, mutect2
- KIF18B | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 265/655 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs758117002; called by muse, mutect2, varscan2
- KIF18B | c.51del p.T18Pfs*35 | Frame Shift Del (DEL) | VAF 139/462 reads (30%) | catalogued as COSV100192143; called by mutect2, pindel, varscan2
- KIF1A | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.291); catalogued as rs555749038, COSV57484275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF1A | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.759); catalogued as rs1240619163; called by muse, mutect2, varscan2
- KIF1C | c.727A>G p.K243E | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs917561706; called by muse, mutect2
- KIF1C | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs769968364; called by muse, mutect2, varscan2
- KIF24 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 126/280 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144194464; called by muse, mutect2, varscan2
- KIF7 | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs567337105; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIFC2 | c.795del p.I266Sfs*12 | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | catalogued as rs781122770; called by mutect2, pindel, varscan2
- KLC3 | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1241996383; called by muse, mutect2, varscan2
- KLHDC4 | c.931T>C p.F311L | Missense Mutation (SNP) | VAF 16/365 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54507938; called by muse, mutect2
- KLHL34 | c.1390C>T p.H464Y | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1359987012; called by muse, mutect2, varscan2
- KLK4 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 146/397 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs564138405; called by muse, mutect2, varscan2
- KLKB1 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs138872241, COSV52996442; called by muse, varscan2
- KMT2A | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.388); catalogued as COSV63283932; called by muse, mutect2, varscan2
- KMT2B | c.7463A>G p.Y2488C | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99720110; called by muse, mutect2, varscan2
- KMT2C | c.2353C>A p.P785T | Missense Mutation (SNP) | VAF 66/382 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs777757726, COSV100068687; called by muse, varscan2
- KMT2C | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.518); catalogued as rs1420335919; called by muse, mutect2, varscan2
- KRBA1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1345536750, COSV55440931; called by muse, mutect2, varscan2
- KRT17 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 174/926 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1294575047; called by muse, varscan2
- KRT17 | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 155/412 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs1443619298; called by muse, varscan2
- KRT87P | n.901_902+1del | Splice Site (DEL) | VAF 86/293 reads (29%) | catalogued as rs777448901; called by pindel, varscan2
- KSR1 | c.1799G>A p.G600D (on ENST00000644974 / NM_001367810.1; = p.G485D on NM_014238.2) | Missense Mutation (SNP) | VAF 250/597 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52032548; called by muse, mutect2, varscan2
- KY | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 120/368 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs774525359, COSV101414934; called by muse, mutect2, varscan2
- LACC1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs752061085, COSV100354846; called by muse, mutect2, varscan2
- LAMA1 | c.7411C>T p.L2471F | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171978061; called by muse, mutect2, varscan2
- LAMA2 | c.2273A>G p.Q758R | Missense Mutation (SNP) | VAF 158/423 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1562395996; called by muse, mutect2, varscan2
- LAMA4 | c.5325A>T p.P1775= (on ENST00000230538 / NM_001105206.3; = p.P1768= on NM_002290.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 91/211 reads (43%) | catalogued as COSV57893567; called by muse, varscan2
- LAMA5 | c.8684G>T p.G2895V | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.549); catalogued as rs754675208; called by muse, mutect2, varscan2
- LANCL1 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV52064392; called by muse, mutect2, varscan2
- LARGE1 | c.1931C>T p.T644I | Missense Mutation (SNP) | VAF 118/321 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV61668211; called by muse, mutect2, varscan2
- LARP6 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.009); catalogued as rs1261473653; called by muse, mutect2, varscan2
- LATS2 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs561166704; called by muse, mutect2, varscan2
- LAYN | c.77T>A p.L26Q | Missense Mutation (SNP) | VAF 17/401 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as rs1225818891; called by muse, mutect2
- LCOR | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs1231181977; called by muse, varscan2
- LDHB | c.714-4del | Splice Region (DEL) | VAF 65/179 reads (36%) | catalogued as rs34439838; called by mutect2, varscan2
- LGALS3BP | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as COSV99431429; called by muse, mutect2, varscan2
- LGR5 | c.2300A>G p.H767R | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57005291; called by muse, mutect2, varscan2
- LHFPL3 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs1219946539; called by muse, mutect2, varscan2
- LILRA1 | c.586A>G p.R196G | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776802122; called by muse, mutect2
- LIX1L | c.1012T>C p.*338Qext*22 | Nonstop Mutation (SNP) | VAF 64/148 reads (43%) | catalogued as rs1444541730; called by muse, mutect2
- LIX1L | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs1382711374; called by muse, mutect2
- LMBRD2 | c.272+2T>C p.X91_splice | Splice Site (SNP) | VAF 43/114 reads (38%) | catalogued as rs1456963845, COSV99683289; called by muse, mutect2, varscan2
- LMF1 | c.1430A>G p.N477S | Missense Mutation (SNP) | VAF 127/335 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as rs1425641489; called by muse, mutect2, varscan2
- LMLN | c.572del p.G191Vfs*55 | Frame Shift Del (DEL) | VAF 59/172 reads (34%) | catalogued as rs1437547243; called by mutect2, pindel
- LMO7 | c.1673G>A p.R558Q (on ENST00000357063; = p.R288Q on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747051266, COSV58536948; called by muse, mutect2, varscan2
- LPAR1 | c.944A>G p.D315G | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62692235; called by muse, mutect2, varscan2
- LPIN2 | c.2066A>C p.D689A | Missense Mutation (SNP) | VAF 168/412 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99078037; called by muse, mutect2, varscan2
- LPP | c.1345A>G p.N449D | Missense Mutation (SNP) | VAF 98/301 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs957362453; called by muse, varscan2
- LRFN3 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 72/416 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.315); catalogued as rs1345568033, COSV55817048; called by muse, mutect2, varscan2
- LRFN3 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.196); catalogued as rs371633389, COSV55818955; called by mutect2, varscan2
- LRP1 | c.8468T>A p.F2823Y | Missense Mutation (SNP) | VAF 164/438 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54520256; called by muse, mutect2, varscan2
- LRP2 | c.6873A>G p.I2291M | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as rs368022337; called by muse, mutect2, varscan2
- LRP3 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs753732125; called by mutect2, varscan2
- LRP4 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs368011278; called by muse, varscan2
- LRRC23 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 165/393 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs781857788, COSV50387719; called by muse, mutect2, varscan2
- LRRC37A2 | c.3616C>T p.L1206F | Missense Mutation (SNP) | VAF 317/1806 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs758340872; called by muse, mutect2, varscan2
- LRRFIP1 | c.1067C>T p.A356V (on ENST00000392000 / NM_001137552.2; = p.A332V on NM_004735.4) | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1203115989; called by muse, mutect2, varscan2
- LRRIQ1 | c.877A>G p.K293E | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs752059594, COSV67840544; called by muse, mutect2, varscan2
- LTBP4 | c.3488C>T p.P1163L (on ENST00000308370 / NM_001042544.1; = p.P1126L on NM_003573.2) | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.18); catalogued as rs1325618259; called by muse, mutect2
- LYST | c.10249A>G p.M3417V | Missense Mutation (SNP) | VAF 202/671 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs767079188; called by muse, mutect2, varscan2
- LYVE1 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56282181; called by muse, mutect2, varscan2
- LYZL4 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as rs573023624; called by muse, mutect2, varscan2
- MACF1 | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 11/251 reads (4%) | catalogued as COSV58370728; called by muse, mutect2
- MAD1L1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 154/408 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs971692328; called by muse, mutect2, varscan2
- MAD2L2 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342200271; called by muse, mutect2, varscan2
- MAGEA4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1309791405; called by muse, mutect2, varscan2
- MAGEC1 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 102/313 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV53573608, COSV53580961; called by muse, mutect2, varscan2
- MAGI3 | c.1825T>C p.W609R | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); catalogued as rs1297787343; called by muse, mutect2
- MAN1C1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as rs1412753671; called by muse, mutect2
- MAN2A1 | c.1305G>A p.W435* | Nonsense Mutation (SNP) | VAF 65/197 reads (33%) | catalogued as COSV99811461; called by muse, mutect2, varscan2
- MAN2A2 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1186215267; called by muse, mutect2, varscan2
- MAP10 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 114/399 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as COSV69364456; called by muse, mutect2, varscan2
- MAP1S | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as rs756780612; called by muse, mutect2, varscan2
- MAP1S | c.2773A>G p.T925A | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1041106402; called by mutect2, varscan2
- MAP3K10 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372587323; called by muse, mutect2, varscan2
- MAP3K13 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 184/470 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1303005657; called by muse, mutect2, varscan2
- MAP3K15 | c.3768G>T p.K1256N | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV58829350; called by muse, mutect2, varscan2
- MAP3K3 | c.474dup p.E159Rfs*26 | Frame Shift Ins (INS) | VAF 22/206 reads (11%) | catalogued as rs1208446998; called by mutect2, pindel
- MAPK1 | c.120C>T p.C40= | Splice Region (SNP) | VAF 32/86 reads (37%) | catalogued as rs146848959; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs1357849329; called by muse, mutect2, varscan2
- MAPKBP1 | c.1985G>A p.G662D (on ENST00000456763 / NM_001128608.2; = p.G656D on NM_014994.3) | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780616739, COSV52957659; called by muse, mutect2, varscan2
- MATR3 | c.1366A>G p.T456A | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as rs748098389; called by muse, varscan2
- MBOAT7 | c.849del p.S284Afs*39 | Frame Shift Del (DEL) | VAF 29/96 reads (30%) | catalogued as rs1382747435; called by mutect2, pindel, varscan2
- MCM2 | c.2132G>A p.G711D | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as COSV99412602, COSV99413714; called by muse, mutect2, varscan2
- MCM8 | c.1562A>T p.D521V | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170534742; called by muse, mutect2, varscan2
- MCRS1 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs766741015; called by muse, varscan2
- MECP2 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs61750239, CM014976, COSV57657805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MED1 | c.865T>C p.S289P | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1294084726; called by muse, mutect2, varscan2
- MED15 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 221/585 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.771); catalogued as rs753090219, COSV99487862; called by muse, mutect2, varscan2
- MED21 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as rs746853397; called by muse, mutect2, varscan2
- MEGF8 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs769196067, COSV52079924; called by muse, mutect2, varscan2
- MEIS3 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as rs1568429878; called by muse, mutect2, varscan2
- MEMO1 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1303988275, COSV54451031; called by muse, mutect2, varscan2
- MEP1A | c.1394A>T p.Y465F | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57920027; called by muse, mutect2, varscan2
- MEPE | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs138152179, COSV100734898; called by muse, mutect2, varscan2
- MEX3D | c.1367A>G p.D456G | Missense Mutation (SNP) | VAF 35/364 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1568263876, COSV66311785; called by muse, mutect2
- MFSD2A | c.1219A>G p.S407G (on ENST00000372809 / NM_001136493.3; = p.S394G on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs1253398805; called by muse, mutect2, varscan2
- MGAM2 | c.5642C>A p.T1881N | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious, low confidence (0.03); catalogued as rs1208812386; called by muse, mutect2, varscan2
- MGAT4B | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 89/334 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.376); catalogued as rs754559279, COSV52977520; called by muse, mutect2, varscan2
- MGAT4D | c.176del p.N59Ifs*5 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as rs1373232850; called by mutect2, pindel, varscan2
- MIA2 | c.1089del p.D364Tfs*8 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as rs538500709; called by mutect2, varscan2
7,386 further variants in this file (4,610 protein-altering or splice-affecting, 1,808 silent, 968 other) are not listed here.
